Gene-level copy-number profile of specimen HCM-CSHL-1263-C24-85M from HCMI case HCM-CSHL-1263-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 76.7 years (28,014 days).
Specimen HCM-CSHL-1263-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 83b1c02e-8959-4c68-87a5-a32bc0cf682e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-1263-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/c6e24fab-c611-4f64-8eb7-eab9c181f310

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 3,879; copy number 2: 22,634; copy number 3: 19,061; copy number 4: 11,159; copy number 5: 1,056; copy number 6: 220; copy number 7: 284; copy number 8: 216; copy number 9: 109; copy number 10: 82; copy number 11: 79; copy number 12: 22; copy number 13: 14; copy number 16: 13; copy number 21: 7; copy number 53: 17; copy number 54: 18; copy number 59: 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–23,438,700, 23 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,138 genes in 50 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:51,789,191–53,186,900, 59 genes, copy number 10 (within-gene range 3–10): NRDC, AL050343.2, AL050343.3, MIR761, TSEN15P2, RAB3B, RNA5SP48, AL445685.2, RN7SL290P, TXNDC12, AL445685.3, KTI12, AL445685.1, TXNDC12-AS1, BTF3L4, ZFYVE9, RN7SL788P, AL139156.2, AL139156.1, PDCL3P6, AL139156.3, DNAJC19P7, ANAPC10P1, CC2D1B, AL513218.1, AL513218.2, PLA2G12AP1, ORC1, PRPF38A, TUT4, AL591167.1, EEF1GP7, GPX7, SHISAL2A, COA7, NDUFS5P3, RN7SL62P, ZYG11B, RNU2-30P, RPS13P2, RNU6-969P, ZYG11A, AC099677.3, ECHDC2, AC099677.1, AC099677.2, SCP2, AC099677.4, AC099677.6, AC099677.5, H3P2, RRAS2P1, TUBBP10, PODN, AL445183.1, HIGD1AP11, SLC1A7, AL445183.2, AL606760.4.
- chr1:53,841,547–58,546,734, 77 genes, copy number 11–12 (within-gene range 3–12) (broad region; genes not listed).
- chr1:59,974,757–77,559,966, 243 genes, copy number 5–21 (broad region; genes not listed).
- chr1:103,687,415–107,505,448, 22 genes, copy number 5: AMY1B, AMYP1, AMY1C, AL136455.1, AC092506.1, FTLP17, CDK4P1, LINC01676, SEPTIN2P1, AL512844.2, AL512844.1, LINC01677, AL355306.2, AL355306.1, AL499605.1, AL596327.1, MTATP6P14, MTCO1P14, LINC01661, PRMT6, NTNG1, NDUFA4P1.
- chr1:108,134,043–114,758,676, 208 genes, copy number 5 (broad region; genes not listed).
- chr1:143,541,768–143,760,669, 9 genes, copy number 5: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1.
- chr2:49,878,623–51,225,575, 6 genes, copy number 5 (within-gene range 4–5): RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1.
- chr2:69,960,089–70,554,193, 19 genes, copy number 6–7: ASPRV1, PCBP1-AS1, RN7SL470P, PCBP1, AC016700.1, MRPL36P1, LINC01816, C2orf42, TIA1, MIR1285-2, RPL39P15, PCYOX1, SNRPG, FAM136A, AC022201.2, BRD7P6, AC022201.1, TGFA, TGFA-IT1.
- chr3:86,876,388–90,261,708, 32 genes, copy number 5–10: VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:138,494,344–165,078,496, 403 genes, copy number 5–7 (broad region; genes not listed).
- chr3:165,186,720–166,862,110, 17 genes, copy number 5: SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1.
- chr3:167,239,843–178,007,779, 153 genes, copy number 5–8 (broad region; genes not listed).
- chr3:179,653,040–180,871,005, 20 genes, copy number 5 (within-gene range 4–5): USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2, AC092939.1, RNA5SP149, AC134503.1, GAPDHP36, RALBP1P1, LINC02053, U8, AC125618.1, RNU6-486P, AC068298.1, TTC14, CCDC39, CCDC39, CCDC39-AS1, AC108734.4.
- chr3:180,820,544–181,836,880, 12 genes, copy number 5 (within-gene range 4–5): AC108734.2, FLYWCH1P1, FXR1, AC108734.1, DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1.
- chr3:181,952,343–182,921,629, 15 genes, copy number 5 (within-gene range 4–5): LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2.
- chr3:183,122,215–183,428,778, 4 genes, copy number 5 (within-gene range 4–5): LAMP3, MCF2L2, B3GNT5, RNA5SP151.
- chr3:184,230,429–186,585,800, 52 genes, copy number 5 (within-gene range 3–5): VWA5B2, MIR1224, ALG3, EEF1AKMT4, EEF1AKMT4-ECE2, CAMK2N2, ECE2, PSMD2, EIF4G1, SNORD66, FAM131A, CLCN2, POLR2H, THPO, CHRD, LINC02054, AC128714.2, LINC01839, LINC01840, EPHB3, MAGEF1, AC107294.2, LINC02069, AC107294.3, AC107294.1, VPS8, C3orf70, EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4, TMEM41A, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B, NMRAL2P, ETV5, Metazoa_SRP, ETV5-AS1, DGKG, LINC02020, LINC02052, LINC02051, CRYGS, TBCCD1, DNAJB11.
- chr7:110,108,031–119,179,149, 109 genes, copy number 5 (broad region; genes not listed).
- chr7:120,005,976–123,103,589, 38 genes, copy number 5: RNU1-29P, AC004946.1, AC004946.2, KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1, CADPS2, AC004594.1, AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1.
- chr7:123,230,120–123,877,481, 13 genes, copy number 5: LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4.
- chr10:54,486,230–54,656,051, 3 genes, copy number 5 (within-gene range 4–5): AL353784.1, NEFMP1, MIR548F1.
- chr10:57,955,295–57,982,993, 2 genes, copy number 5: AC006484.1, MRPS35P3.
- chr10:60,026,298–60,733,490, 2 genes, copy number 5 (within-gene range 4–5): ANK3, AL592430.1.
- chr10:60,139,912–60,741,828, 3 genes, copy number 5: AL592430.2, ARL4AP1, ANK3-DT.
- chr11:4,994,851–5,138,356, 12 genes, copy number 5: OR51L1, OR51P1P, OR52J2P, OR52J3, OR52E2, OR52E1, OR52S1P, OR52E3P, OR52J1P, AC113331.1, OR52A4P, OR52A5.
- chr11:74,000,277–74,171,210, 3 genes, copy number 5–6 (within-gene range 3–6): UCP3, C2CD3, AP002392.1.
- chr11:86,441,108–91,116,555, 112 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr11:97,222,644–97,657,582, 2 genes, copy number 9: LINC02553, RNA5SP347.
- chr11:100,641,975–101,209,591, 8 genes, copy number 16: RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1.
- chr11:101,915,010–102,683,913, 21 genes, copy number 12 (within-gene range 2–12): CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2.
- chr11:108,008,678–109,823,893, 26 genes, copy number 6–16: AP003307.1, CUL5, Y_RNA, AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1, AP003102.1, LINC02715.
- chr11:109,907,004–111,475,397, 24 genes, copy number 6–13 (within-gene range 4–13): TFAMP2, RPSAP50, AP001981.1, AP001889.1, ZC3H12C, LINC02732, FDX1, ARHGAP20, HNRNPA1P60, AP002963.1, RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1, COLCA2, MIR4491, POU2AF1, RNU2-60P, AP002008.3, AP002008.2.
- chr11:134,945,118–134,980,574, 2 genes, copy number 8: AP003062.2, LINC02697.
- chr12:54,802,746–63,360,037, 256 genes, copy number 6–9 (broad region; genes not listed).
- chr12:68,610,855–70,637,440, 50 genes, copy number 9–59: RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:80,343,515–80,937,925, 11 genes, copy number 6–9 (within-gene range 3–9): RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618.
- chr12:96,985,656–97,598,415, 19 genes, copy number 8–9 (within-gene range 3–9): AC007656.2, AC007656.1, AC007656.3, AC007656.4, LINC02409, RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6.
- chr18:22,164,886–23,586,506, 27 genes, copy number 5–6 (within-gene range 3–6): GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1.
- chr21:7,744,962–8,761,335, 30 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666.
- chr22:18,906,028–18,947,732, 3 genes, copy number 21 (within-gene range 3–21): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 1,535. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
